CPTAC case C3N-01754 — Other and unspecified parts of tongue — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a18e0ff1-792a-472a-a6f0-aa85d4e1cd95

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Tongue, NOS; Age at diagnosis: 64.1 years (23,404 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,903 days (5.2 years); Progression or recurrence: no; Days to last follow up: 1,903 days (5.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 5; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 456 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 30; ECOG performance status: 3.
- Days to follow up: 654 days (1.8 years); Disease response: Tumor Free; Karnofsky performance status: 50; ECOG performance status: 2.
- Days to follow up: 994 days (2.7 years); Disease response: Tumor Free; Karnofsky performance status: 50; ECOG performance status: 2.
- Days to follow up: 1,535 days (4.2 years); Disease response: Complete Response; Karnofsky performance status: 50; ECOG performance status: 2.
- Days to follow up: 1,535 days (4.2 years); Disease response: Tumor Free; Karnofsky performance status: 50; ECOG performance status: 2.
- Days to follow up: 1,903 days (5.2 years); Disease response: Tumor Free; Karnofsky performance status: 50; ECOG performance status: 2.

Other clinical attributes
- Weight: 77 kg; Height: 185 cm; BMI: 22.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 41; Cigarettes per day: 20; Tobacco smoking onset year: 1975; Tobacco smoking quit year: 2016; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 41; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01754-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 75 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01754-22: Section location: Tongue; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3N-01754-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 35 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01754-23: Section location: Tongue; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-01754-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 102 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01754-24: Section location: Tongue; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3N-01754-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 216 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01754-14: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01754-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -13 days; Method of sample procurement: Blood Draw.
